Gene-level copy-number profile of tumor specimen TCGA-GI-A2C9-01A from TCGA case TCGA-GI-A2C9, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 59.0 years (21,534 days).
Specimen TCGA-GI-A2C9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.49f9eae1-6d7c-45a8-bcf1-b321f980a581.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GI-A2C9-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 824 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/63a943f1-2037-4a19-b65a-7c875ac2205b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 2,221; copy number 2: 22,190; copy number 3: 19,867; copy number 4: 10,795; copy number 5: 1,954; copy number 6: 1,851; copy number 7: 688; copy number 8: 207; copy number 9: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GI-A2C9-01A-11D-A21P-01): tumor purity 0.81, ploidy 1.68, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:18,651,147–18,718,526, 2 genes: RN7SKP258, RAP1BP1.
- chr17:142,789–386,254, 7 genes (within-gene range 0–2): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,633 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,712,999–121,580,524, 79 genes, copy number 6 (broad region; genes not listed).
- chr1:211,376,834–245,134,090, 685 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:245,206,444–245,234,501, 1 gene, copy number 5: KIF26B-AS1.
- chr1:245,749,342–248,919,946, 136 genes, copy number 6 (broad region; genes not listed).
- chr3:11,745–8,745,040, 78 genes, copy number 5 (broad region; genes not listed).
- chr3:8,750,408–8,769,628, 1 gene, copy number 5 (within-gene range 3–5): OXTR.
- chr3:149,761,100–149,968,385, 1 gene, copy number 6 (within-gene range 4–6): ANKUB1.
- chr3:149,812,770–198,222,513, 860 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr4:71,062,667–77,040,384, 106 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr6:17,582,034–21,602,383, 55 genes, copy number 5: SUMO2P13, AL138824.1, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA, KIF13A, AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr7:56,805,336–57,837,046, 70 genes, copy number 6 (broad region; genes not listed).
- chr8:99,960,936–100,131,268, 1 gene, copy number 6 (within-gene range 4–6): RGS22.
- chr8:100,023,982–145,066,685, 708 genes, copy number 5–9 (broad region; genes not listed).
- chr10:44,712–26,697,625, 441 genes, copy number 6–8 (broad region; genes not listed).
- chr10:33,578,931–38,783,108, 95 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr11:34,049,967–43,840,030, 98 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:43,718,676–43,734,564, 4 genes, copy number 5: AC068205.3, RPL23AP63, PHBP2, AC068205.4.
- chr11:56,848,478–59,845,499, 140 genes, copy number 5 (broad region; genes not listed).
- chr12:66,767–34,058,745, 843 genes, copy number 6–9 (broad region; genes not listed).
- chr16:11,555–181,179, 22 genes, copy number 5: DDX11L10, WASH4P, MIR6859-4, Z84723.1, WASIR2, IL9RP3, POLR3K, SNRNP25, RHBDF1, Z69720.2, MPG, NPRL3, Z69720.1, Z69666.1, HBZ, HBM, HBZP1, HBAP1, HBA2, HBA1, Y_RNA, HBQ1.
- chr21:44,768,580–46,665,124, 70 genes, copy number 7 (broad region; genes not listed).
- chr22:29,505,879–32,464,484, 139 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,969. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
